Gene-level copy-number profile of tumor specimen AP-EZEX-YT from APOLLO case AP-EZEX, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Invasive mucinous adenocarcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3.
Specimen AP-EZEX-YT: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2c3f241b-2d2c-47e8-8318-e7f9e2b64951.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-EZEX-FR (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/47763b45-4222-4377-b8e5-da909dd42038

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,319; copy number 2: 48,554; copy number 3: 4,464; copy number 4: 422; copy number 5: 69; copy number 6: 3; copy number 7: 13; copy number 8: 26; copy number 9: 7; copy number 10: 28; copy number 11: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 154 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:30,466,452–30,926,459, 37 genes, copy number 8–10: TMPOP1, SUCLA2P1, RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640, GTF2H4, AL669830.1, VARS2.
- chr6:41,381,392–43,450,427, 77 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr6:60,719,222–61,574,402, 7 genes, copy number 7: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9.
- chr20:22,343,693–22,685,344, 6 genes, copy number 7: AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747.
- chr20:53,567,065–53,668,758, 3 genes, copy number 6 (within-gene range 3–6): ZNF217, AC005808.1, RNU7-14P.
- chr20:63,865,228–64,101,162, 24 genes, copy number 5: TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3.

Autosomal genes at a single copy (total copy number 1): 2,463. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
